Gene-level copy-number profile of tumor specimen TCGA-06-0238-01A from TCGA case TCGA-06-0238, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.6 years (17,037 days).
Specimen TCGA-06-0238-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.7d4e57d3-9137-4cd3-94ed-e38292849e54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0238-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e987037-6a45-49b2-a1e2-92b4cd0ee6d9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,133; copy number 3: 3,362; copy number 4: 46,908; copy number 6: 3,320; copy number 11: 49; copy number 35: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0238-01A-02D-0310-01): tumor purity 0.78, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 95 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:57,452,323–57,978,277, 46 genes, copy number 35: INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65.
- chr16:2,429,394–2,859,726, 49 genes, copy number 11: CCNF, AC106820.6, MIR6767, AC106820.3, AC106820.5, TEDC2, MIR6768, AC106820.2, NTN3, TBC1D24, AC106820.4, AC093525.2, ATP6V0C, AC093525.1, AC093525.8, AMDHD2, CEMP1, MIR3178, PDPK1, AC093525.6, AC093525.5, AC093525.7, AC093525.4, AC093525.3, AC093525.9, AC093525.10, AC141586.5, AC141586.3, AC141586.1, PDPK2P, AC141586.4, AC141586.2, ERVK13-1, KCTD5, AC092117.2, PRSS27, SRRM2-AS1, SRRM2, ELOB, AC092117.1, PRSS33, SNORA3C, PRSS41, PRSS21, EIF1P4, ZG16B, PRSS30P, PRSS22, AC003965.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
